TARGET case TARGET-30-PAMLWV — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Retroperitoneum and peritoneum. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/a90cda3a-a43e-5843-bdfd-b822aad63a32

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 5.0 years (1,820 days); Year of diagnosis: 2003; Days to last follow up: 1,111 days (3.0 years); INSS stage: Stage 4.
